Gene-level copy-number profile of tumor specimen TCGA-13-0765-01A from TCGA case TCGA-13-0765, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 50.9 years (18,574 days).
Specimen TCGA-13-0765-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 26624f62-b93e-4218-a0ba-b2685140f0b7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-13-0765-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,246 have no estimate.
https://portal.gdc.cancer.gov/files/317a2673-9c64-4af0-a4bd-63b8ad5c3364

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 80; copy number 1: 22,797; copy number 2: 32,440; copy number 3: 2,749; copy number 4: 293; copy number 5: 18.

Homozygous deletions (total copy number 0; autosomes only): 79 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:130,459,455–130,509,707, 2 genes: POTEI, RNU6-473P.
- chr4:4,117,925–4,150,421, 3 genes: AC116562.1, OR7E103P, UNC93B4.
- chr4:9,459,255–9,484,702, 2 genes: OR7E86P, OR7E85P.
- chr4:133,871,246–134,010,690, 1 gene: AC079380.1.
- chr4:181,522,666–181,523,001, 1 gene: AC093840.1.
- chr5:96,525,267–96,935,809, 7 genes (within-gene range 0–1): CAST, AC020900.1, ERAP1, AC008906.1, AC008906.2, AC009126.1, ERAP2.
- chr5:96,942,299–96,943,184, 1 gene (within-gene range 0–1): AC008850.1.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr5:139,341,587–139,628,434, 16 genes (within-gene range 0–1): PAIP2, AC135457.1, SLC23A1, MZB1, PROB1, SPATA24, DNAJC18, AC142391.1, RNU5B-4P, ECSCR, STING1, AC138517.1, NCOA4P4, UBE2D2, Y_RNA, H3P25.
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.
- chr6:37,815,777–37,819,218, 1 gene: AL121574.1.
- chr6:125,797,856–125,818,858, 1 gene (within-gene range 0–1): NCOA7-AS1.
- chr15:21,843,750–21,981,245, 7 genes: MIR3118-4, POTEB, RNU6-631P, ZNF519P3, NF1P2, MIR5701-3, OR11J6P.
- chr15:34,489,002–34,588,503, 6 genes: HNRNPLP2, FSCN1P1, DNM1P5, GOLGA8B, MIR1233-2, AC027139.1.
- chr16:24,610,209–24,827,632, 1 gene (within-gene range 0–1): TNRC6A.
- chr16:24,803,451–25,111,555, 11 genes: AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5.
- chr16:68,530,090–68,835,541, 14 genes: ZFP90, RNU4-36P, AC126773.3, AC126773.6, AC126773.1, AC126773.2, CDH3, AC126773.4, AC126773.5, HSPE1P5, CDH1, RNA5SP429, AC099314.1, FTLP14.
- chr22:18,906,028–18,947,732, 3 genes (within-gene range 0–1): DGCR6, AC007326.4, PRODH.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:2,695,765–2,812,902, 1 gene, copy number 5 (within-gene range 2–5): ITFG2-AS1.
- chr12:2,781,904–3,072,145, 16 genes, copy number 5: RPL23AP14, CBX3P4, FKBP4, ITFG2-AS1, AC005841.1, ITFG2, NRIP2, TEX52, FOXM1, RHNO1, TULP3, AC005911.1, RNU6-1315P, TEAD4, AC125807.2, AC125807.1.
- chr14:45,891,087–46,501,903, 1 gene, copy number 5: LINC00871.

Autosomal genes at a single copy (total copy number 1): 20,687. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
